Somatic mutation profile of tumor specimen TCGA-LD-A7W5-01A (aliquot TCGA-LD-A7W5-01A-22D-A351-09) from TCGA case TCGA-LD-A7W5, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 52.5 years (19,169 days).
Specimen TCGA-LD-A7W5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 74540a13-6bc4-41b9-ab1c-9d6e0d515289.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LD-A7W5-10A (Blood Derived Normal), aliquot TCGA-LD-A7W5-10A-01D-A351-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da9e5f60-c637-450a-a0f3-d7a0dca3610c

The open-access MAF lists 38 somatic variants for this specimen: 29 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 24, Silent 9, Nonsense Mutation 2, Splice Region 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKL5 | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs122460159, CM081207, COSV66113460; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.770T>G p.L257R | Missense Mutation (SNP) | VAF 6/21 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934577, CD941800, CM1411657, CM941332, COSV52682484, COSV52703253, COSV52757928; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS20 | c.951G>A p.E317= | Splice Region (SNP) | VAF 7/40 reads (18%) | catalogued as COSV101239112; called by muse, mutect2, varscan2
- ADAMTS3 | c.1726C>T p.R576C | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1359140245, COSV54397513, COSV99710659; called by muse, mutect2, varscan2
- ANKRD44 | c.904C>G p.Q302E | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV99984536; called by muse, mutect2
- CENPJ | c.2932G>A p.E978K | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101121485; called by muse, mutect2, varscan2
- COL11A2 | c.4873G>A p.V1625M (on ENST00000341947 / NM_080680.3; = p.V1518M on NM_080679.2) | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as rs754205211, COSV100553669; called by muse, mutect2, varscan2
- DIP2A | c.3177C>G p.F1059L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV100595546; called by muse, mutect2, varscan2
- DLGAP1 | c.1966-2A>G p.X656_splice | Splice Site (SNP) | VAF 14/62 reads (23%) | catalogued as COSV100229145; called by muse, mutect2
- DPAGT1 | c.1169G>A p.G390D | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as COSV99597880; called by muse, mutect2, varscan2
- ECHS1 | c.300C>G p.I100M | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100881891; called by muse, mutect2, varscan2
- ESF1 | c.2371G>C p.E791Q | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.878); catalogued as rs773024021, COSV99176304; called by muse, mutect2, varscan2
- FST | c.940G>A p.G314R | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370731523; called by muse, mutect2, varscan2
- GBGT1 | c.931T>A p.S311T | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.78); PolyPhen benign (0.306); catalogued as COSV100923765; called by muse, mutect2, varscan2
- GRIPAP1 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.885); catalogued as COSV100904243; called by muse, mutect2, varscan2
- HEATR5B | c.268C>T p.Q90* | Nonsense Mutation (SNP) | VAF 8/74 reads (11%) | catalogued as COSV99248818; called by muse, mutect2, varscan2
- HSD3B2 | c.298A>C p.N100H | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101027445; called by muse, mutect2
- LEPR | c.232C>T p.H78Y | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60759524, COSV60765396; called by muse, mutect2
- LRG1 | c.529C>T p.R177W | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as rs1405758232, COSV56705708; called by muse, mutect2
- MRC1 | c.909G>A p.W303* | Nonsense Mutation (SNP) | VAF 32/151 reads (21%) | catalogued as COSV99519334; called by muse, mutect2, varscan2
- MUC16 | c.37871G>T p.S12624I | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.282); catalogued as COSV101199169; called by muse, mutect2, varscan2
- NR1H4 | c.1064C>T p.P355L (on ENST00000551379 / NM_001206993.2; = p.P341L on NM_005123.4) | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as rs768234999, COSV51852328; called by muse, mutect2, varscan2
- PADI1 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.431); catalogued as rs142259163; called by muse, mutect2, varscan2
- POU3F4 | c.563C>T p.T188M | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as rs1304011557, COSV64541856; ClinVar: likely benign; called by muse, mutect2, varscan2
- SFMBT1 | c.663G>T p.W221C | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99965926; called by muse, mutect2, varscan2
- SPRYD7 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1349329152, COSV100709816; called by muse, mutect2, varscan2
- STARD8 | c.1838A>G p.K613R | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.762); catalogued as COSV99366553; called by muse, mutect2, varscan2
- WASHC5 | c.2897A>G p.N966S | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as rs1466814960, COSV100572714; called by muse, mutect2, varscan2
- DYRK1A | c.1478dup p.S494Ifs*79 | Frame Shift Ins (INS) | VAF 14/50 reads (28%) | called by mutect2, pindel, varscan2
- AJM1 | c.36G>A p.S12= | Silent (SNP) | VAF 16/168 reads (10%) | catalogued as COSV56032828; called by muse, mutect2
- CACNA1B | c.5898G>A p.G1966= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as rs771393649, COSV99496247; called by muse, mutect2, varscan2
- CEP250 | c.7038C>T p.A2346= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as rs776127915, COSV100698839; called by muse, mutect2, varscan2
- CLDN10 | c.93G>A p.K31= | Silent (SNP) | VAF 9/102 reads (9%) | catalogued as COSV100176088; called by muse, mutect2, varscan2
- MACROD2 | c.510G>A p.K170= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV99429376; called by muse, mutect2, varscan2
- NOS1 | c.1740C>T p.G580= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as rs973123429, COSV100500312; called by mutect2, varscan2
- PLCB4 | c.363A>C p.V121= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV99594892; called by muse, mutect2, varscan2
- SVOP | c.1305G>A p.A435= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as rs575951583, COSV54469177; called by muse, mutect2, varscan2
- ZNF224 | c.129C>T p.N43= | Silent (SNP) | VAF 11/84 reads (13%) | catalogued as rs1159403544, COSV100425345; called by muse, mutect2, varscan2
